Somatic mutation profile of tumor specimen 0DM4XO from CCDI case PBCAEH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Parietal lobe; Age at diagnosis: 0.3 years (115 days).
Specimen 0DM4XO: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5db5cc88-53d6-460d-a495-427544dee49c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DM4XA (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d62d83be-3216-4245-9e20-c0298c7d1420

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAP2 | c.1990C>T p.P664S | Missense Mutation (SNP) | VAF 161/1340 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.598); catalogued as COSV52281904; called by muse, mutect2, varscan2
- NEO1 | c.3824G>A p.R1275H | Missense Mutation (SNP) | VAF 111/2093 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.932); catalogued as rs1390138135; called by muse, mutect2
- CD69 | c.527T>A p.L176Q | Missense Mutation (SNP) | VAF 37/916 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2
- CSF1R | c.1636_1653del p.Y546_K551del | In Frame Del (DEL) | VAF 491/1677 reads (29%) | called by pindel, varscan2*
